MMRF case MMRF_2240 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0084e8b6-57fc-48b6-aa77-fec6e45161d2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.1 years (24,502 days); ISS stage: III; Days to last known disease status: 832 days (2.3 years); Days to last follow up: 832 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 90 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 68 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 91 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 91 days; Days to treatment end: 202 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 202 days; Days to treatment end: 672 days (1.8 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 733 days (2.0 years); Days to treatment end: 733 days (2.0 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 735 days (2.0 years); Days to treatment end: 735 days (2.0 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 846 days (2.3 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 849 days (2.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 6.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.404 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 119 mg/dL; Immunoglobulin G 77.6 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 12.5 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 4.46 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 191 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.53 mmol/L; Albumin 32 g/L; Total Protein 11.4 g/dL; Glucose 4.4 mmol/L; C-Reactive Protein 2.26 mg/dL.
- Day 76 (ECOG 1): M Protein 4.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.105 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 44.1 mg/dL; Immunoglobulin G 66.8 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.43 mmol/L; Albumin 31 g/L; Total Protein 10.7 g/dL; Glucose 5.12 mmol/L.
- Day 158 (ECOG 1): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.073 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.3 mg/dL; Immunoglobulin G 48.4 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.85 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 9.9 g/dL; Glucose 4.95 mmol/L.
- Day 256 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.098 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.68 mg/dL; Immunoglobulin G 22.5 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7.9 g/dL; Glucose 4.18 mmol/L.
- Day 342 (ECOG 1): M Protein 2.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.14 mg/dL; Immunoglobulin G 23.6 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 4.17 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL; Glucose 4.18 mmol/L.
- Day 433 (ECOG 1): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.488 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.09 mg/dL; Immunoglobulin G 20.6 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 4.79 mmol/L.
- Day 516 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.134 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.74 mg/dL; Immunoglobulin G 17.4 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 4.1 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.4 mmol/L.
- Day 643 (ECOG 1): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.109 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.04 mg/dL; Immunoglobulin G 17.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 4.02 mmol/L.
- Day 705 (ECOG 1): M Protein 1.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.81 mg/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 4.72 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 306 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 6.7 g/dL; Glucose 4.79 mmol/L.
- Day 832 (ECOG 1): M Protein 1.74 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.143 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.85 mg/dL; Immunoglobulin G 23.7 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.24 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 8 g/dL; Glucose 4.24 mmol/L.

Other clinical attributes
- Day 1: Weight: 77 kg; Height: 168 cm.

Biospecimens (2 samples)
- Sample MMRF_2240_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2240_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
